Somatic mutation profile of tumor specimen TCGA-05-4415-01A (aliquot TCGA-05-4415-01A-22D-1855-08) from TCGA case TCGA-05-4415, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 57.2 years (20,880 days).
Specimen TCGA-05-4415-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7b413fc5-9285-4a73-93d6-7e09afd478d0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-05-4415-10A (Blood Derived Normal), aliquot TCGA-05-4415-10A-01D-1855-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dcc7b0a6-7b05-4fa1-8dbc-72cb9188a548

The open-access MAF lists 215 somatic variants for this specimen: 164 protein-altering or splice-affecting, 49 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 147, Silent 49, Splice Site 5, Nonsense Mutation 4, Frame Shift Del 3, Frame Shift Ins 2, Splice Region 2, In Frame Del 1, 3'Flank 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 16/28 reads (57%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PROS1 | c.701A>G p.Y234C | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs387906675, CM103688, COSV62398166; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.375G>T p.T125= | Splice Region (SNP) | VAF 39/61 reads (64%) | catalogued as rs55863639, CS004351, CS011573, CS971913, COSV52665709, COSV52718605, COSV52726641, COSV53120615; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.6302C>A p.T2101N (on ENST00000272895 / NM_173076.3; = p.T1783N on NM_015657.3) | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as COSV55954459, COSV99787737; called by muse, mutect2, varscan2
- ABCC11 | c.3386C>T p.T1129I | Missense Mutation (SNP) | VAF 27/45 reads (60%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as COSV62322278; called by muse, mutect2, varscan2
- ABCF1 | c.227A>G p.K76R | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.028); catalogued as rs191359115, COSV58227883, COSV58228632; called by muse, mutect2, varscan2
- ADAM20 | c.1255G>T p.E419* | Nonsense Mutation (SNP) | VAF 77/235 reads (33%) | catalogued as COSV56454558; called by muse, mutect2, varscan2
- ADAMTS12 | c.2400G>T p.Q800H | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV61255556, COSV61255597, COSV61259962; called by muse, mutect2, varscan2
- ADAMTS19 | c.983C>A p.P328H | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.885); catalogued as COSV50739558, COSV50804662; called by muse, mutect2, varscan2
- ADGRE3 | c.1850T>A p.V617E | Missense Mutation (SNP) | VAF 67/112 reads (60%) | SIFT tolerated (0.58); PolyPhen benign (0.005); catalogued as COSV53729605, COSV53732823; called by muse, mutect2, varscan2
- ALDH8A1 | c.1322G>T p.G441V | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55641085; called by muse, mutect2, varscan2
- AMER3 | c.1990G>C p.G664R | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as COSV58465956; called by muse, mutect2, varscan2
- ARFGEF2 | c.3666G>T p.W1222C | Missense Mutation (SNP) | VAF 36/63 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64211579; called by muse, mutect2, varscan2
- ASH1L | c.2671G>A p.G891S | Missense Mutation (SNP) | VAF 139/221 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV64206858; called by muse, mutect2, varscan2
- ATP1A4 | c.241A>T p.T81S | Missense Mutation (SNP) | VAF 33/256 reads (13%) | SIFT tolerated (0.48); PolyPhen benign (0.014); catalogued as COSV63626035; called by muse, mutect2, varscan2
- BBS9 | c.2468G>T p.G823V (on ENST00000242067 / NM_001348036.1; = p.G783V on NM_014451.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54162573; called by muse, mutect2, varscan2
- BLID | c.199C>A p.L67I | Missense Mutation (SNP) | VAF 78/140 reads (56%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.432); catalogued as COSV73340205; called by muse, mutect2, varscan2
- BNC1 | c.2755C>A p.L919I | Missense Mutation (SNP) | VAF 92/299 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.112); catalogued as COSV61757048; called by muse, mutect2, varscan2
- BRINP3 | c.2044G>C p.D682H | Missense Mutation (SNP) | VAF 30/149 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); catalogued as COSV66519064; called by muse, mutect2, varscan2
- BRIP1 | c.113G>T p.S38I | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.465); catalogued as COSV51997205; called by muse, mutect2, varscan2
- C2orf78 | c.1967T>A p.L656Q | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); catalogued as COSV68517119; called by muse, mutect2, varscan2
- CACNA1E | c.985C>A p.L329M | Missense Mutation (SNP) | VAF 150/233 reads (64%) | SIFT tolerated (0.19); PolyPhen benign (0.394); catalogued as COSV62388587; called by muse, mutect2, varscan2
- CALM1 | c.210G>T p.L70F | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.67); catalogued as COSV63662816; called by muse, mutect2, varscan2
- CDH10 | c.382C>A p.R128S | Missense Mutation (SNP) | VAF 57/176 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.781); catalogued as COSV52576463; called by muse, mutect2, varscan2
- CDH6 | c.2032A>G p.R678G | Missense Mutation (SNP) | VAF 4/88 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV54067341; called by muse, mutect2
- CDHR1 | c.572G>C p.R191P | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60561263; called by muse, mutect2, varscan2
- CDYL | c.24G>T p.R8S | Missense Mutation (SNP) | VAF 24/34 reads (71%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as COSV61038830; called by muse, mutect2, varscan2
- CHST5 | c.1124T>C p.L375P | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV60338320; called by muse, mutect2, varscan2
- CLVS2 | c.38T>A p.L13Q | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.02); catalogued as COSV51560607; called by muse, mutect2, varscan2
- COL24A1 | c.1051G>T p.V351L | Missense Mutation (SNP) | VAF 47/97 reads (48%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs1175835087, COSV65304524; called by muse, mutect2, varscan2
- COL7A1 | c.6602G>T p.G2201V | Missense Mutation (SNP) | VAF 38/60 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60393643; called by muse, mutect2, varscan2
- CRB1 | c.2261C>A p.A754D | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV66329355, COSV66332707; called by muse, mutect2, varscan2
- CRISPLD1 | c.249G>A p.M83I | Missense Mutation (SNP) | VAF 57/108 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51546320, COSV51550707; called by muse, mutect2, varscan2
- CSAG3 | c.318C>G p.F106L | Missense Mutation (SNP) | VAF 85/213 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.916); catalogued as rs1232784999; called by muse, mutect2, varscan2
- CSNK1A1L | c.731C>A p.P244H | Missense Mutation (SNP) | VAF 48/77 reads (62%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV65789528; called by muse, varscan2
- CTSV | c.396+1G>T p.X132_splice | Splice Site (SNP) | VAF 17/47 reads (36%) | catalogued as COSV52344587; called by muse, mutect2, varscan2
- DENND2A | c.929C>G p.S310C | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.068); catalogued as COSV52049554; called by muse, mutect2, varscan2
- DGKZ | c.794G>T p.C265F (on ENST00000454345 / NM_001105540.2; = p.C76F on NM_003646.4) | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.096); catalogued as COSV58986913; called by muse, mutect2, varscan2
- DMBT1 | c.607G>A p.A203T | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.054); catalogued as COSV57539769; called by muse, mutect2, varscan2
- DSC3 | c.1102G>A p.A368T | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as COSV64572450; called by muse, mutect2, varscan2
- EEF1AKMT3 | c.295del p.X99_splice | Splice Site (DEL) | VAF 31/53 reads (58%) | catalogued as rs756314578; called by mutect2, pindel, varscan2
- EEPD1 | c.185G>T p.R62L | Missense Mutation (SNP) | VAF 234/304 reads (77%) | SIFT deleterious (0.04); PolyPhen benign (0.189); catalogued as COSV54197068, COSV54198786; called by muse, mutect2, varscan2
- ENDOD1 | c.636A>T p.K212N | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.183); catalogued as COSV99566401; called by muse, mutect2, varscan2
- ENKD1 | c.404G>A p.R135H | Missense Mutation (SNP) | VAF 45/180 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs747403734, COSV54666801; called by muse, mutect2, varscan2
- ENOX2 | c.90G>T p.M30I (on ENST00000338144 / NM_001382520.1; = p.M1? on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 61/75 reads (81%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.003); catalogued as COSV57649759; called by muse, mutect2, varscan2
- EPPK1 | c.421G>A p.V141I | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs782129650, COSV73261018; called by muse, mutect2, varscan2
- FER1L6 | c.1873C>A p.P625T | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV101205540; called by muse, mutect2, varscan2
- FER1L6 | c.1874C>A p.P625H | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.401); catalogued as COSV101205542; called by muse, mutect2, varscan2
- FGD2 | c.133C>A p.P45T | Missense Mutation (SNP) | VAF 40/66 reads (61%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV51462953; called by muse, mutect2, varscan2
- FMN1 | c.4039A>T p.T1347S (on ENST00000616417 / NM_001277313.2; = p.T1124S on NM_001103184.4) | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.444); catalogued as COSV57920736; called by muse, mutect2, varscan2
- FOLR3 | c.145C>A p.P49T | Missense Mutation (SNP) | VAF 71/199 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs999511898, COSV61530009; called by muse, mutect2, varscan2
- FSHR | c.476C>A p.T159K | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV58620970; called by muse, mutect2, varscan2
- GABRA2 | c.569C>A p.T190K | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV62913677; called by muse, mutect2, varscan2
- GBP4 | c.524C>A p.P175H | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.181); catalogued as COSV63253784; called by muse, mutect2, varscan2
- GMPS | c.1577A>G p.Y526C | Missense Mutation (SNP) | VAF 67/189 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1358300899, COSV55808729; called by muse, mutect2, varscan2
- GNGT2 | c.13C>A p.L5I | Missense Mutation (SNP) | VAF 121/313 reads (39%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.832); catalogued as COSV55929810; called by muse, mutect2, varscan2
- GNRHR | c.415C>A p.R139S | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM066865, COSV56933216, COSV56933808; called by muse, mutect2, varscan2
- GREB1 | c.2153G>A p.G718E | Missense Mutation (SNP) | VAF 56/158 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as COSV52184185; called by muse, mutect2, varscan2
- GRIP1 | c.2801C>A p.T934K (on ENST00000359742 / NM_001379345.1; = p.T882K on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 86/118 reads (73%) | SIFT tolerated (0.06); PolyPhen benign (0.137); catalogued as COSV54020072; called by muse, mutect2, varscan2
- HCN1 | c.1681C>A p.L561I | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV57502518; called by muse, mutect2, varscan2
- HMCN1 | c.7302G>T p.R2434S | Missense Mutation (SNP) | VAF 67/117 reads (57%) | SIFT tolerated (0.09); PolyPhen benign (0.243); catalogued as COSV54889882; called by muse, mutect2, varscan2
- HTR6 | c.667G>T p.A223S | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.952); catalogued as COSV57032713; called by muse, mutect2, varscan2
- IGHV1-46 | c.223G>T p.G75C | Missense Mutation (SNP) | VAF 97/250 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs190309173; called by muse, mutect2, varscan2
- IL12RB1 | c.1492G>A p.V498M | Missense Mutation (SNP) | VAF 12/16 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs374771268; called by muse, mutect2, varscan2
- INO80C | c.526G>T p.D176Y | Missense Mutation (SNP) | VAF 89/267 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as COSV58047163; called by muse, mutect2, varscan2
- ITGAM | c.730G>A p.G244R | Missense Mutation (SNP) | VAF 58/134 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs748727423, COSV54935731; called by muse, mutect2, varscan2
- ITGAX | c.2626-1G>T p.X876_splice | Splice Site (SNP) | VAF 17/107 reads (16%) | catalogued as COSV51644138; called by muse, mutect2, varscan2
- JPH4 | c.380G>A p.G127D | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV62508512, COSV62509702; called by muse, mutect2
- KCNH7 | c.114C>A p.N38K | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.708); catalogued as COSV59792572; called by muse, mutect2, varscan2
- KIAA1217 | c.4039C>G p.Q1347E | Missense Mutation (SNP) | VAF 54/143 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.266); catalogued as COSV56814977; called by muse, mutect2, varscan2
- KIF4B | c.1734G>T p.L578F | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775125448, COSV70528679; called by muse, mutect2, varscan2
- KIF4B | c.3518G>T p.C1173F | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT tolerated (0.64); PolyPhen benign (0.019); catalogued as COSV70528685; called by muse, mutect2, varscan2
- KLHL7 | c.169G>T p.A57S (on ENST00000339077 / NM_001031710.3; = p.A9S on NM_018846.5) | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV59160644; called by muse, mutect2, varscan2
- KRT17 | c.605C>A p.A202D | Missense Mutation (SNP) | VAF 63/186 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV60860434; called by muse, mutect2, varscan2
- KRT24 | c.64G>T p.A22S | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.001); catalogued as COSV52880000; called by muse, mutect2, varscan2
- LNPK | c.577G>T p.V193L | Missense Mutation (SNP) | VAF 57/170 reads (34%) | SIFT tolerated (0.43); PolyPhen benign (0.055); catalogued as COSV55823160; called by muse, mutect2, varscan2
- LRP12 | c.2465G>T p.R822L | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.68); catalogued as COSV52627468; called by muse, mutect2, varscan2
- LSAMP | c.125C>T p.T42I | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.667); catalogued as COSV61284216; called by muse, mutect2, varscan2
- LTB4R | c.361C>A p.R121S | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.082); catalogued as COSV51865248; called by muse, mutect2, varscan2
- MAP3K3 | c.1088G>T p.R363L | Missense Mutation (SNP) | VAF 58/164 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as COSV62279635; called by muse, mutect2, varscan2
- MCM3 | c.862G>A p.A288T (on ENST00000229854 / NM_001366374.2; = p.A278T on NM_002388.6 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 45/67 reads (67%) | SIFT tolerated (0.29); PolyPhen benign (0.059); catalogued as rs775943986, COSV57717153; called by muse, mutect2, varscan2
- MIOS | c.1398G>C p.M466I | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV100402990, COSV60767882; called by muse, mutect2, varscan2
- MYCBP2 | c.13231A>G p.I4411V (on ENST00000357337; = p.I4449V on NM_015057.5) | Missense Mutation (SNP) | VAF 40/131 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62014608; called by muse, mutect2, varscan2
- MYH14 | c.1066G>T p.G356* | Nonsense Mutation (SNP) | VAF 27/66 reads (41%) | catalogued as COSV51814156, COSV99221407; called by muse, mutect2, varscan2
- MYH4 | c.1218A>T p.R406S | Missense Mutation (SNP) | VAF 73/132 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV55115800; called by muse, mutect2, varscan2
- NAV3 | c.5574C>A p.N1858K (on ENST00000397909 / NM_001024383.2; = p.N1836K on NM_014903.6) | Missense Mutation (SNP) | VAF 64/76 reads (84%) | SIFT tolerated (0.1); PolyPhen benign (0.304); catalogued as COSV57072239; called by muse, mutect2, varscan2
- NBEAL2 | c.5278G>T p.A1760S | Missense Mutation (SNP) | VAF 22/37 reads (59%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs538047537, COSV52756233; called by muse, mutect2, varscan2
- NUAK1 | c.517G>T p.G173C | Missense Mutation (SNP) | VAF 119/147 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54602125; called by muse, mutect2, varscan2
- OR10X1 | c.544G>T p.D182Y | Missense Mutation (SNP) | VAF 52/91 reads (57%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.481); catalogued as COSV63767194, COSV63767296; called by muse, mutect2, varscan2
- OR2G3 | c.413C>T p.P138L | Missense Mutation (SNP) | VAF 154/256 reads (60%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as COSV100180873, COSV60681280; called by muse, mutect2, varscan2
- OR51E2 | c.187T>G p.C63G | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV67807171; called by muse, mutect2, varscan2
- OR51G2 | c.31A>T p.S11C | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.299); catalogued as COSV58992414; called by muse, mutect2, varscan2
- OR56A3 | c.234C>A p.C78* | Nonsense Mutation (SNP) | VAF 80/213 reads (38%) | catalogued as rs1325139913, COSV61568792; called by muse, mutect2, varscan2
- OR5L2 | c.667A>G p.T223A | Missense Mutation (SNP) | VAF 53/149 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.103); catalogued as COSV65723733; called by muse, mutect2, varscan2
- OR5W2 | c.702G>T p.R234S | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.367); catalogued as rs375899233, COSV60615384; called by muse, mutect2, varscan2
- OTOGL | c.2254C>T p.H752Y (on ENST00000547103; = p.H743Y on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 50/60 reads (83%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.484); catalogued as COSV101509037; called by muse, mutect2, varscan2
- PAPPA2 | c.1576C>T p.R526C | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs200777009, COSV62775934; called by muse, mutect2, varscan2
- PCDHA7 | c.1282C>T p.R428W | Missense Mutation (SNP) | VAF 82/223 reads (37%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.605); catalogued as rs566217489, COSV65342591; called by muse, mutect2, varscan2
- PCDHB5 | c.1945C>T p.P649S | Missense Mutation (SNP) | VAF 39/108 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.976); catalogued as rs17844424, COSV50647129; called by muse, mutect2, varscan2
- PCDHB6 | c.125C>A p.T42K | Missense Mutation (SNP) | VAF 52/135 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs782184538, COSV50690911, COSV50693213; called by muse, mutect2, varscan2
- PCDHGA1 | c.188G>T p.G63V | Missense Mutation (SNP) | VAF 70/173 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); catalogued as COSV65295881; called by muse, mutect2, varscan2
- PCDHGA11 | c.770G>T p.S257I | Missense Mutation (SNP) | VAF 68/214 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.296); catalogued as COSV53924707; called by muse, mutect2, varscan2
- PCOLCE | c.1090T>C p.Y364H | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56157990; called by muse, mutect2, varscan2
- PEG3 | c.1744C>A p.Q582K | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.191); catalogued as rs1482740003, COSV55629793; called by muse, mutect2, varscan2
- PKD1L1 | c.3941G>A p.G1314E | Missense Mutation (SNP) | VAF 33/137 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.977); catalogued as COSV56961899; called by muse, mutect2, varscan2
- PLD2 | c.740A>G p.Y247C | Missense Mutation (SNP) | VAF 92/146 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54005036; called by muse, mutect2, varscan2
- PPEF2 | c.2225C>T p.A742V | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as COSV54421409; called by muse, mutect2, varscan2
- PPME1 | c.764T>A p.I255K | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.109); catalogued as COSV60296214; called by muse, mutect2, varscan2
- PREX1 | c.2067C>A p.N689K | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.75); PolyPhen benign (0.006); catalogued as COSV64250247; called by muse, mutect2, varscan2
- PRIM2 | c.53G>T p.R18M | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.347); catalogued as COSV51424618; called by muse, mutect2, varscan2
- PSG2 | c.599G>T p.R200M | Missense Mutation (SNP) | VAF 244/585 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1157464477, COSV61544910; called by muse, mutect2, varscan2
- PSMD14 | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs1293113776, COSV68832108; called by muse, mutect2, varscan2
- PTH | c.271G>T p.V91F | Missense Mutation (SNP) | VAF 37/175 reads (21%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.554); catalogued as COSV56378320; called by muse, mutect2, varscan2
- PTPRD | c.199C>G p.Q67E | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.508); catalogued as COSV61937304; called by muse, mutect2, varscan2
- RAD51AP2 | c.2086G>T p.D696Y | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.322); catalogued as COSV67587721; called by muse, mutect2, varscan2
- RAP1GDS1 | c.1351G>T p.V451L | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.782); catalogued as COSV52786063; called by muse, mutect2
- RB1 | c.2267A>G p.Y756C | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99923579; called by muse, mutect2, varscan2
- RIMS2 | c.1565C>A p.T522K (on ENST00000666250 / NM_001348490.2; = p.T330K on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51662033, COSV51669215; called by muse, mutect2, varscan2
- RIPOR2 | c.1296C>A p.S432R | Missense Mutation (SNP) | VAF 39/50 reads (78%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.668); catalogued as COSV52419289; called by muse, mutect2, varscan2
- RNF185 | c.115T>A p.C39S | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV56735234; called by muse, mutect2, varscan2
- RO60 | c.1318-1G>C p.X440_splice | Splice Site (SNP) | VAF 39/62 reads (63%) | catalogued as COSV66473552; called by muse, mutect2, varscan2
- ROCK1 | c.384G>T p.M128I | Missense Mutation (SNP) | VAF 46/112 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67695345; called by muse, mutect2, varscan2
- RP1L1 | c.1208C>A p.P403H | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV66753654; called by muse, mutect2, varscan2
- RPTOR | c.413G>T p.R138L | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60806260, COSV60808190; called by muse, mutect2, varscan2
- SCML2 | c.1043G>T p.G348V | Missense Mutation (SNP) | VAF 32/50 reads (64%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.457); catalogued as COSV52620043; called by muse, mutect2, varscan2
- SEZ6L | c.559G>T p.D187Y | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.094); catalogued as COSV50660613; called by muse, mutect2, varscan2
- SGO2 | c.3600A>T p.K1200N | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV63414695, COSV63415337; called by muse, mutect2, varscan2
- SLC25A12 | c.1172-1G>T p.X391_splice | Splice Site (SNP) | VAF 49/118 reads (42%) | catalogued as COSV55532483, COSV55532908; called by muse, mutect2, varscan2
- SLC2A14 | c.183C>A p.I61= | Splice Region (SNP) | VAF 17/83 reads (20%) | catalogued as COSV100533619, COSV61587993; called by muse, mutect2, varscan2
- SND1 | c.333G>T p.M111I | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as COSV61238516; called by muse, mutect2, varscan2
- SNX15 | c.847G>A p.E283K | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1386133025, COSV57246435; called by muse, mutect2, varscan2
- SPG7 | c.708G>T p.E236D | Missense Mutation (SNP) | VAF 53/118 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV51949198; called by muse, mutect2, varscan2
- SPTAN1 | c.2516G>A p.R839H | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.953); catalogued as rs779633188, COSV63986322; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- STAB2 | c.599C>T p.A200V | Missense Mutation (SNP) | VAF 146/191 reads (76%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as COSV66337231; called by muse, mutect2, varscan2
- SULT1B1 | c.664G>A p.D222N | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT tolerated (0.31); PolyPhen benign (0.029); catalogued as COSV60207184; called by muse, mutect2, varscan2
- SYT16 | c.1226G>T p.G409V | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV70855036, COSV70855957; called by muse, mutect2, varscan2
- TBPL2 | c.139T>A p.C47S | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.001); catalogued as COSV55972251; called by muse, mutect2, varscan2
- THSD7B | c.1701G>T p.K567N | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.875); catalogued as COSV55672004, COSV99750081; called by muse, mutect2, varscan2
- TLR9 | c.2656T>G p.W886G | Missense Mutation (SNP) | VAF 66/201 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62346226; called by muse, mutect2, varscan2
- TMTC1 | c.700C>A p.L234I (on ENST00000539277 / NM_001193451.2; = p.L126I on NM_175861.3) | Missense Mutation (SNP) | VAF 49/64 reads (77%) | SIFT tolerated (0.1); PolyPhen benign (0.338); catalogued as COSV55478824; called by muse, mutect2, varscan2
- TNN | c.2781G>T p.R927S | Missense Mutation (SNP) | VAF 63/91 reads (69%) | SIFT tolerated (0.15); PolyPhen benign (0.069); catalogued as COSV53424151; called by muse, mutect2, varscan2
- TOP2A | c.2135A>T p.E712V | Missense Mutation (SNP) | VAF 42/121 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.119); catalogued as COSV70732383; called by muse, mutect2, varscan2
- TRIM39 | c.377G>C p.C126S | Missense Mutation (SNP) | VAF 61/88 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100935647; called by muse, mutect2, varscan2
- TRIM51 | c.503G>T p.W168L | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.077); catalogued as COSV55265463; called by muse, mutect2, varscan2
- TTN | c.44974G>T p.E14992* (on ENST00000591111; = p.E7568* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 14/52 reads (27%) | catalogued as COSV59974577, COSV60339537; called by muse, mutect2, varscan2
- UBE2O | c.2347G>T p.A783S | Missense Mutation (SNP) | VAF 76/204 reads (37%) | SIFT tolerated (0.73); PolyPhen benign (0.026); catalogued as COSV60061796; called by muse, mutect2, varscan2
- UNC13C | c.877A>T p.T293S | Missense Mutation (SNP) | VAF 69/214 reads (32%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.018); catalogued as COSV52859172; called by muse, mutect2, varscan2
- VRTN | c.787C>A p.P263T | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as COSV56440058; called by muse, mutect2, varscan2
- XYLT1 | c.2261G>A p.R754H | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs555809214, COSV54479221, COSV54481523; called by muse, mutect2, varscan2
- ZEB2 | c.2392A>T p.S798C | Missense Mutation (SNP) | VAF 82/226 reads (36%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.533); catalogued as COSV57954575; called by muse, mutect2, varscan2
- ZMAT4 | c.440G>T p.C147F | Missense Mutation (SNP) | VAF 126/354 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52694988; called by muse, mutect2, varscan2
- ZNF235 | c.1979G>A p.C660Y | Missense Mutation (SNP) | VAF 62/158 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52156009; called by muse, mutect2, varscan2
- ZNF467 | c.1661G>T p.R554L | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.189); catalogued as rs756635234, COSV100117769, COSV100117802; called by muse, mutect2, varscan2
- ZNF638 | c.5430G>C p.K1810N | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs1192371180, COSV52484763; called by muse, mutect2, varscan2
- ZNF746 | c.610G>T p.V204L | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.502); catalogued as rs776180012, COSV61406968; called by muse, mutect2, varscan2
- ZNF804B | c.3832C>A p.P1278T | Missense Mutation (SNP) | VAF 55/221 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.123); catalogued as COSV60822964; called by muse, mutect2, varscan2
- ZP4 | c.1313T>A p.V438E | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63911604; called by muse, mutect2
- ARHGEF15 | c.219dup p.A74Cfs*9 | Frame Shift Ins (INS) | VAF 30/58 reads (52%) | called by mutect2, pindel, varscan2
- CCDC174 | c.1306dup p.T436Nfs*23 | Frame Shift Ins (INS) | VAF 32/58 reads (55%) | called by mutect2, pindel, varscan2
- CD226 | c.216del p.K73Sfs*10 | Frame Shift Del (DEL) | VAF 34/83 reads (41%) | called by mutect2, pindel, varscan2
- PROX1 | c.1517del p.G506Efs*10 | Frame Shift Del (DEL) | VAF 82/167 reads (49%) | called by mutect2, pindel, varscan2
- STK11 | c.683_696del p.L228Rfs*33 | Frame Shift Del (DEL) | VAF 20/29 reads (69%) | called by mutect2, pindel, varscan2
- UBC | c.1529G>T p.R510L | Missense Mutation (SNP) | VAF 6/8 reads (75%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- ZNF608 | c.3315_3323del p.E1106_Y1108del | In Frame Del (DEL) | VAF 32/104 reads (31%) | called by mutect2, pindel, varscan2
- ABCA13 | c.11034G>T p.A3678= | Silent (SNP) | VAF 110/468 reads (24%) | catalogued as COSV101447002, COSV71285327; called by muse, mutect2, varscan2
- ACTG2 | c.30G>T p.V10= | Silent (SNP) | VAF 18/53 reads (34%) | catalogued as COSV61828019; called by muse, mutect2, varscan2
- ARHGAP17 | c.2364G>A p.Q788= (on ENST00000289968 / NM_001006634.3; = p.Q710= on NM_018054.6) | Silent (SNP) | VAF 26/129 reads (20%) | catalogued as COSV51505954; called by muse, mutect2, varscan2
- ATRNL1 | c.3288C>T p.R1096= | Silent (SNP) | VAF 56/143 reads (39%) | catalogued as COSV58081532; called by muse, mutect2, varscan2
- B3GAT3 | c.504C>A p.L168= | Silent (SNP) | VAF 39/100 reads (39%) | catalogued as COSV53881889; called by muse, mutect2, varscan2
- CACNA1C | c.3747C>A p.I1249= | Silent (SNP) | VAF 42/88 reads (48%) | catalogued as COSV59708040; called by muse, mutect2, varscan2
- CAD | c.3996G>T p.V1332= | Silent (SNP) | VAF 46/124 reads (37%) | catalogued as COSV53025315; called by muse, mutect2, varscan2
- CAPN6 | c.462C>A p.S154= | Silent (SNP) | VAF 40/55 reads (73%) | catalogued as COSV60694461; called by muse, mutect2, varscan2
- CFAP206 | c.1119G>A p.A373= | Silent (SNP) | VAF 28/64 reads (44%) | catalogued as rs183010552, COSV99739227; called by muse, mutect2, varscan2
- CLEC14A | c.549C>T p.R183= | Silent (SNP) | VAF 46/102 reads (45%) | catalogued as rs1451872800, COSV60562172; called by muse, mutect2, varscan2
- COL9A3 | c.1656C>T p.S552= | Silent (SNP) | VAF 40/564 reads (7%) | catalogued as COSV58984148; called by muse, mutect2
- DHX38 | c.2745C>T p.P915= | Silent (SNP) | VAF 20/46 reads (43%) | catalogued as rs762977085, COSV51697323; called by muse, mutect2, varscan2
- DNAAF1 | c.903T>A p.A301= | Silent (SNP) | VAF 60/136 reads (44%) | catalogued as COSV57576842; called by muse, mutect2, varscan2
- DYNC2H1 | c.8973A>T p.A2991= | Silent (SNP) | VAF 71/175 reads (41%) | catalogued as COSV62090888; called by muse, mutect2, varscan2
- ELP1 | c.1935A>T p.A645= | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as COSV65897085; called by muse, mutect2, varscan2
- ENOX1 | c.724C>A p.R242= | Silent (SNP) | VAF 78/114 reads (68%) | catalogued as COSV54893880, COSV54894744; called by muse, mutect2, varscan2
- EPX | c.1627C>A p.R543= | Silent (SNP) | VAF 48/123 reads (39%) | catalogued as COSV56595749; called by muse, mutect2, varscan2
- FAM180A | c.354C>A p.L118= | Silent (SNP) | VAF 63/124 reads (51%) | catalogued as COSV58528228; called by muse, mutect2, varscan2
- FBLN2 | c.3189C>A p.V1063= | Silent (SNP) | VAF 10/16 reads (63%) | catalogued as rs746401754, COSV55482782; called by mutect2, varscan2
- FOXF1 | c.921C>T p.H307= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as rs764736637, COSV99296387; called by muse, mutect2, varscan2
- HCN1 | c.2541G>T p.S847= | Silent (SNP) | VAF 42/132 reads (32%) | catalogued as COSV57502512; called by muse, mutect2, varscan2
- IGF2BP3 | c.693C>A p.V231= | Silent (SNP) | VAF 32/171 reads (19%) | catalogued as COSV51682606; called by muse, mutect2, varscan2
- IGLV1-47 | c.189C>A p.A63= | Silent (SNP) | VAF 111/233 reads (48%) | called by muse, mutect2, varscan2
- KCNMA1 | c.2043T>C p.H681= | Silent (SNP) | VAF 38/108 reads (35%) | catalogued as rs146803262; called by muse, mutect2, varscan2
- KRT85 | c.1029C>T p.N343= | Silent (SNP) | VAF 105/144 reads (73%) | catalogued as COSV57736450; called by muse, mutect2, varscan2
- LILRA4 | c.9C>A p.L3= | Silent (SNP) | VAF 18/61 reads (30%) | catalogued as COSV52491359; called by muse, mutect2, varscan2
- MAML3 | c.351C>T p.T117= | Silent (SNP) | VAF 12/21 reads (57%) | catalogued as rs1053139096, COSV72208859; called by muse, mutect2, varscan2
- MIA2 | c.1470T>C p.N490= | Silent (SNP) | VAF 58/149 reads (39%) | catalogued as COSV54482805; called by muse, mutect2, varscan2
- MTMR9 | c.1377C>T p.S459= | Silent (SNP) | VAF 39/99 reads (39%) | catalogued as rs1200381724, COSV55311647; called by muse, mutect2, varscan2
- MYO7B | c.1965C>A p.I655= | Silent (SNP) | VAF 22/52 reads (42%) | catalogued as COSV67346289; called by muse, mutect2, varscan2
- NUP188 | c.1824G>A p.V608= | Silent (SNP) | VAF 58/208 reads (28%) | catalogued as COSV65361255; called by muse, mutect2, varscan2
- OR10J3 | c.453G>T p.G151= | Silent (SNP) | VAF 57/95 reads (60%) | catalogued as COSV100171756, COSV59954027; called by muse, mutect2, varscan2
- PCDH15 | c.2799G>T p.G933= | Silent (SNP) | VAF 27/58 reads (47%) | catalogued as COSV57287455; called by muse, mutect2, varscan2
- PCLO | c.15345C>A p.A5115= | Silent (SNP) | VAF 91/177 reads (51%) | catalogued as COSV61626086; called by muse, mutect2, varscan2
- PCSK2 | c.1668C>A p.T556= | Silent (SNP) | VAF 17/68 reads (25%) | catalogued as COSV52729898; called by muse, mutect2, varscan2
- PKD1L2 | c.117C>T p.C39= | Silent (SNP) | VAF 50/93 reads (54%) | catalogued as rs1165876465, COSV61413777; called by muse, mutect2, varscan2
- PRSS58 | c.525G>A p.T175= | Silent (SNP) | VAF 26/126 reads (21%) | catalogued as rs150069777; called by muse, mutect2, varscan2
- RAP1GDS1 | c.1353G>T p.V451= | Silent (SNP) | VAF 24/57 reads (42%) | catalogued as COSV52786072; called by muse, mutect2
- SALL1 | c.1264T>C p.L422= | Silent (SNP) | VAF 104/208 reads (50%) | catalogued as COSV51755659; called by muse, mutect2, varscan2
- SLC36A3 | c.1189C>T p.L397= | Silent (SNP) | VAF 29/72 reads (40%) | catalogued as rs771196036, COSV58856433; called by muse, mutect2, varscan2
- STC2 | c.15G>T p.R5= | Silent (SNP) | VAF 62/181 reads (34%) | catalogued as COSV54179206; called by muse, mutect2, varscan2
- TAOK2 | c.3360G>A p.K1120= | Silent (SNP) | VAF 28/132 reads (21%) | catalogued as COSV54229342; called by muse, mutect2, varscan2
- TBX4 | c.1509G>A p.R503= | Silent (SNP) | VAF 29/76 reads (38%) | catalogued as COSV53606239; called by muse, mutect2, varscan2
- TDRD6 | c.2916A>T p.L972= | Silent (SNP) | VAF 44/62 reads (71%) | catalogued as COSV60174881; called by muse, mutect2, varscan2
- TENM3 | c.5781C>T p.D1927= | Silent (SNP) | VAF 31/73 reads (42%) | catalogued as COSV69303836; called by muse, mutect2, varscan2
- TLK1 | c.1398C>A p.G466= | Silent (SNP) | VAF 16/80 reads (20%) | catalogued as COSV62629132, COSV62629705; called by muse, mutect2, varscan2
- WDFY3 | c.7518A>G p.Q2506= | Silent (SNP) | VAF 35/114 reads (31%) | catalogued as COSV55697458; called by muse, mutect2, varscan2
- WDR33 | c.2514G>T p.G838= | Silent (SNP) | VAF 23/55 reads (42%) | catalogued as COSV59247632; called by muse, mutect2, varscan2
- WIPI2 | c.438G>A p.K146= | Silent (SNP) | VAF 40/158 reads (25%) | catalogued as COSV56588010; called by muse, mutect2, varscan2
- NTRK3 | c.1890-1774C>G | Intron (SNP) | VAF 10/37 reads (27%) | called by mutect2, varscan2
- POM121 | chr7:72949353 C>T | 3'Flank (SNP) | VAF 9/27 reads (33%) | catalogued as COSV99987752; called by muse, mutect2, varscan2
